CCDI case PBCTAX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/df17a635-fb94-4464-b46b-04a4af2eed0a

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.7 years (6,098 days).

Biospecimens (2 samples)
- Sample 0DYP42: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYP44: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
